Somatic mutation profile of tumor specimen TCGA-A7-A5ZX-01A (aliquot TCGA-A7-A5ZX-01A-12D-A29N-09) from TCGA case TCGA-A7-A5ZX, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 48.4 years (17,683 days).
Specimen TCGA-A7-A5ZX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a532755-c7ae-4cd9-8873-d827ffd5ea6e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A7-A5ZX-10A (Blood Derived Normal), aliquot TCGA-A7-A5ZX-10A-01D-A29N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9fbdb18-81df-48d6-9bdc-14fd8d7aedea

The open-access MAF lists 31 somatic variants for this specimen: 25 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 20, Silent 6, Splice Site 2, Frame Shift Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BOLA1 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs1318430369, COSV64967449; called by muse, mutect2, varscan2
- BRF2 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1251717807, COSV55105084; called by muse, mutect2, varscan2
- CDH1 | c.2191del p.L731Ffs*39 | Frame Shift Del (DEL) | VAF 28/116 reads (24%) | catalogued as COSV55728672, COSV55738690; called by mutect2, pindel, varscan2
- CHD4 | c.2590C>T p.R864W (on ENST00000357008 / NM_001363606.2; = p.R877W on NM_001273.5) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58898273; called by muse, mutect2, varscan2
- DMD | c.5587-1G>C p.X1863_splice | Splice Site (SNP) | VAF 14/53 reads (26%) | catalogued as COSV63747777, COSV63781174; called by muse, mutect2, varscan2
- FIBIN | c.268C>A p.Q90K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.457); catalogued as COSV59413353; called by muse, mutect2, varscan2
- FRMPD4 | c.700C>T p.Q234* | Nonsense Mutation (SNP) | VAF 3/40 reads (8%) | catalogued as COSV101042723; called by muse, mutect2
- HOXA11 | c.330C>A p.S110R | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as COSV50054221; called by muse, mutect2, varscan2
- IQCG | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.994); catalogued as COSV54564846; called by muse, mutect2, varscan2
- MCAM | c.1794-2A>T p.X598_splice | Splice Site (SNP) | VAF 5/33 reads (15%) | catalogued as COSV50654314; called by muse, mutect2
- MGA | c.7933T>G p.L2645V (on ENST00000219905 / NM_001164273.1; = p.L2436V on NM_001080541.2) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.76); catalogued as COSV54960788; called by muse, mutect2, varscan2
- MMP16 | c.1639G>A p.D547N | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as COSV54163036, COSV54183051; called by muse, mutect2, varscan2
- NAV1 | c.3127A>G p.M1043V | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as COSV99818703; called by muse, mutect2
- OR10H5 | c.754C>A p.H252N | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100454697; called by muse, mutect2
- OR11H12 | c.334T>C p.C112R | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV73569324; called by mutect2, varscan2
- OTOS | c.267C>G p.D89E | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.012); catalogued as COSV100108833; called by muse, mutect2
- PCCA | c.1532G>A p.G511D | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66197204; called by muse, mutect2, varscan2
- RAD51AP2 | c.2137T>C p.C713R | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); catalogued as COSV67588829; called by muse, mutect2, varscan2
- RANBP2 | c.2389C>G p.P797A | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV51697355, COSV99311971; called by muse, mutect2
- RFPL2 | c.739G>A p.V247M | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.97); catalogued as rs779821935, COSV50715348; called by muse, mutect2, varscan2
- SCARB2 | c.1222G>A p.V408M | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99357908; called by muse, mutect2
- SLITRK6 | c.1348A>T p.I450L | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV68391309; called by muse, mutect2, varscan2
- SMARCC1 | c.2171G>A p.R724Q | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.428); catalogued as rs746452222, COSV54384775; called by muse, mutect2, varscan2
- VWA5A | c.1886G>A p.R629Q | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.048); catalogued as rs763551541, COSV64412797; called by muse, mutect2
- TBX3 | c.981_984del p.E327Dfs*33 (on ENST00000257566 / NM_016569.4; = p.E307Dfs*33 on NM_005996.4) | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | called by mutect2, pindel, varscan2
- C2CD3 | c.894G>A p.K298= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV58093318; called by muse, mutect2, varscan2
- DNAJC22 | c.286C>T p.L96= | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as COSV101222517; called by muse, mutect2
- NRG3 | c.2076C>T p.L692= (on ENST00000404547 / NM_001370084.1; = p.L668= on NM_001010848.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs1243672742, COSV64567358; called by muse, mutect2
- PCCB | c.1590T>G p.P530= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV52447560; called by muse, mutect2, varscan2
- PCDHB11 | c.2061C>T p.T687= | Silent (SNP) | VAF 14/144 reads (10%) | catalogued as rs782115049, COSV61310768; called by muse, mutect2
- RPS6KA2 | c.126C>T p.D42= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as COSV99690666; called by muse, mutect2
